Somatic mutation profile of tumor specimen MP2PRT-PAVRUY-TMP1-A (aliquot MP2PRT-PAVRUY-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVRUY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,900 days).
Specimen MP2PRT-PAVRUY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93ca101e-16fd-4c59-8d53-4041e56b956c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRUY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRUY-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf539341-288c-4900-a9fe-ea1e12895443

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 72/274 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 33/407 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2
- KRTAP6-2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 114/548 reads (21%) | PolyPhen benign (0.025); catalogued as rs1430104173; called by muse, mutect2, varscan2
- PPP2R5B | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51213221; called by muse, mutect2, varscan2
- PRAMEF20 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as rs1200392559; called by muse, mutect2, varscan2
- ADAM28 | c.1867G>T p.A623S | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- AGBL1 | c.359A>C p.H120P | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- EFS | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 219/928 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MRRF | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- TECTA | c.3357G>T p.Q1119H | Missense Mutation (SNP) | VAF 18/553 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- TGIF2LX | c.29A>G p.E10G | Missense Mutation (SNP) | VAF 13/435 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- UGGT2 | c.4484T>A p.I1495K | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF408 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 30/620 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- APBB2 | c.192C>A p.P64= | Silent (SNP) | VAF 177/642 reads (28%) | called by muse, mutect2, varscan2
- ESS2 | c.462C>T p.R154= | Silent (SNP) | VAF 143/391 reads (37%) | called by muse, mutect2, varscan2
- FASN | c.5016C>T p.L1672= | Silent (SNP) | VAF 223/743 reads (30%) | called by muse, mutect2, varscan2
- KREMEN1 | c.177C>T p.N59= (on ENST00000407188; = p.N61= on NM_032045.5) | Silent (SNP) | VAF 93/352 reads (26%) | catalogued as rs777107449; called by muse, mutect2, varscan2
- TASOR2 | c.2856T>C p.S952= | Silent (SNP) | VAF 99/366 reads (27%) | catalogued as rs1184483836; called by muse, mutect2, varscan2
- TTC6 | c.318G>A p.A106= | Silent (SNP) | VAF 34/916 reads (4%) | catalogued as rs977512302; called by muse, mutect2
